Gene-level copy-number profile of tumor specimen HCM-CSHL-0184-C25-01A from HCMI case HCM-CSHL-0184-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 77.3 years (28,240 days).
Specimen HCM-CSHL-0184-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 17b879ca-61fd-4636-a8f6-f422948ab649.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0184-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/8024cd0c-d14c-415d-bc3f-69fa58da04a4

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 2; copy number 2: 10,655; copy number 3: 1,054; copy number 4: 24,286; copy number 5: 8,145; copy number 6: 9,191; copy number 7: 3,343; copy number 8: 1,045; copy number 9: 82; copy number 10: 405; copy number 11: 11; copy number 12: 38; copy number 15: 5; copy number 16: 9; copy number 22: 81; copy number 62: 3; copy number 87: 6; copy number 112: 25.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,751,512–87,880,427, 5 genes: ATAD1, CFL1P1, RN7SL78P, KLLN, AC063965.2.
- chr14:73,537,143–73,543,796, 2 genes (within-gene range 0–5): ACOT1, NT5CP2.
- chr14:106,436,415–106,461,055, 4 genes (within-gene range 0–5): AC244452.1, IGHVII-40-1, IGHV3-41, HOMER2P1.
- chr14:106,470,264–106,470,800, 1 gene (within-gene range 0–5): IGHV3-43.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 665 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,269,491–38,300,322, 6 genes, copy number 11 (within-gene range 6–11): TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10.
- chr7:73,293,497–92,917,187, 296 genes, copy number 10–112 (broad region; genes not listed).
- chr8:40,519,565–43,674,591, 84 genes, copy number 9–12 (broad region; genes not listed).
- chr9:33,041,765–35,865,518, 145 genes, copy number 10–22 (within-gene range 2–22) (broad region; genes not listed).
- chr11:50,170,156–50,422,316, 9 genes, copy number 11–15: AC109635.3, AC109635.6, PHKG1P3, AC109635.4, AC109635.2, AC109635.1, LINC02750, AC024405.2, AC024405.1.
- chr14:22,123,318–22,540,306, 88 genes, copy number 10 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 10: TRAC.
- chr14:59,479,274–61,083,733, 36 genes, copy number 12 (within-gene range 8–12): AL121694.1, JKAMP, CCDC175, RTN1, MIR5586, AL133299.1, LRRC9, AL157911.1, PCNX4, DHRS7, SCOCP1, PSMA3P1, RPL17P2, AL157756.1, PPM1A, LINC02322, C14orf39, RBM8B, GNRHR2P1, SALL4P7, SIX6, AL049874.3, AL049874.4, AL049874.2, AL049874.1, SALRNA1, SIX1, SIX4, MNAT1, MAD2L1P1, AL160236.2, SRMP2, TRMT5, AL160236.1, RNU6-398P, SLC38A6.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
